Somatic mutation profile of tumor specimen TCGA-KK-A7AY-01A (aliquot TCGA-KK-A7AY-01A-11D-A33T-08) from TCGA case TCGA-KK-A7AY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.8 years (22,220 days).
Specimen TCGA-KK-A7AY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca962d29-b8c5-426e-91d9-8a31a22c3232.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7AY-11A (Solid Tissue Normal), aliquot TCGA-KK-A7AY-11A-21D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3229d72-e46a-40ca-b4e2-0f16e89dae94

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 8, Frame Shift Del 5, Nonsense Mutation 4, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMDEC1 | c.1381G>A p.G461R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs146989743; called by muse, mutect2, varscan2
- AKR1C3 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.061); catalogued as COSV101003069, COSV65910655; called by muse, mutect2, varscan2
- BBX | c.2096G>A p.S699N | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1356462336, COSV100361487; called by muse, mutect2, varscan2
- CARD11 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 30/42 reads (71%) | catalogued as COSV62754868; called by muse, mutect2, varscan2
- CCDC85A | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.556); catalogued as rs1250701844, COSV101339462; called by muse, mutect2
- CD69 | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as rs764551801, COSV99946069, COSV99946231; called by muse, mutect2, varscan2
- CFAP61 | c.2918C>G p.A973G | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV99844632; called by muse, mutect2, varscan2
- COLGALT1 | c.1011G>C p.K337N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV99395024; called by muse, mutect2, varscan2
- CORIN | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.058); catalogued as COSV99903560; called by muse, mutect2, varscan2
- DDX18 | c.443A>C p.E148A | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV54305463; called by muse, mutect2, varscan2
- DLX6 | c.794del p.S265Ifs*28 | Frame Shift Del (DEL) | VAF 20/39 reads (51%) | catalogued as COSV50293693; called by mutect2, pindel, varscan2
- ESX1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65424903; called by muse, mutect2
- FEM1A | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV99521430; called by muse, mutect2, varscan2
- GRIA1 | c.2563C>T p.R855W | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs759869812, COSV53590645; called by muse, mutect2, varscan2
- HCN1 | c.1378-1G>A p.X460_splice | Splice Site (SNP) | VAF 30/80 reads (38%) | catalogued as COSV100300098; called by muse, mutect2, varscan2
- HECTD2 | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs757949507, COSV99978518; called by muse, mutect2, varscan2
- HLTF | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369660600, COSV100026832; called by muse, mutect2
- IQCA1 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1437782516, COSV99609406; called by muse, mutect2, varscan2
- KRT3 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs772349450, COSV58815778; called by muse, mutect2, varscan2
- LCE2C | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.418); catalogued as COSV100909432; called by muse, mutect2, varscan2
- LYPLAL1 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as rs775363916, COSV100859690; called by muse, mutect2, varscan2
- NID1 | c.3398C>T p.A1133V | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs753021292, COSV99937442; called by muse, mutect2, varscan2
- PDZK1 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as COSV100777346, COSV100777366; called by mutect2, varscan2
- PRPF8 | c.4850G>A p.R1617Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1242961736, COSV100517137; called by muse, mutect2, varscan2
- PTH1R | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as COSV100480956; called by muse, mutect2
- PTPRC | c.3145A>G p.M1049V | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61410829; called by muse, mutect2, varscan2
- RAMP1 | c.190A>G p.R64G | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99614666; called by muse, mutect2, varscan2
- SLC44A4 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57669005; called by muse, mutect2, varscan2
- SNRPG | c.15C>G p.H5Q | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99231930; called by muse, mutect2, varscan2
- SPAG9 | c.3337C>G p.R1113G (on ENST00000262013 / NM_001130528.3; = p.R1099G on NM_003971.6) | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100004409, COSV100005122; called by muse, mutect2, varscan2
- STYK1 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as rs1172518849, COSV50015322; called by muse, mutect2, varscan2
- TPH2 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as rs147025898, CM109150, COSV61592994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTBK2 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99141433; called by muse, mutect2, varscan2
- CYP4Z1 | c.1509del p.V504Ffs*36 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- SMAD2 | c.1387_1390del p.C463Qfs*16 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- TPD52L1 | c.231del p.N77Kfs*3 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | called by mutect2, pindel, varscan2
- TRAJ12 | c.10A>G p.S4G | Missense Mutation (SNP) | VAF 34/85 reads (40%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ZKSCAN5 | c.887_888del p.F296Cfs*5 | Frame Shift Del (DEL) | VAF 19/109 reads (17%) | called by mutect2, pindel, varscan2
- CES5A | c.165C>T p.N55= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs776161802, COSV51868680; called by muse, mutect2, varscan2
- LILRB1 | c.2067A>T p.P689= (on ENST00000427581; = p.P638= on NM_006669.6) | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV100207256; called by muse, mutect2, varscan2
- MAB21L1 | c.270C>T p.D90= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs760166578, COSV100079709; called by muse, mutect2, varscan2
- NAV2 | c.2829C>T p.D943= (on ENST00000396087 / NM_001244963.2; = p.D920= on NM_145117.5) | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs143699420; called by muse, mutect2, varscan2
- NEB | c.13533G>C p.V4511= | Silent (SNP) | VAF 21/290 reads (7%) | catalogued as COSV99421761, COSV99425209; called by muse, mutect2
- SLC4A9 | c.1860C>T p.G620= (on ENST00000507527 / NM_001258428.2; = p.G596= on NM_031467.3) | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as rs763106509, COSV99138790; called by muse, mutect2, varscan2
- XRCC6 | c.864C>T p.L288= | Silent (SNP) | VAF 67/190 reads (35%) | catalogued as COSV100777787, COSV100777820; called by muse, mutect2, varscan2
- ZNF577 | c.918C>G p.T306= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100030990; called by muse, mutect2, varscan2
- ZNF99 | c.*720T>C | 3'UTR (SNP) | VAF 12/39 reads (31%) | catalogued as rs577414244, COSV101233817; called by muse, mutect2, varscan2
